Somatic mutation profile of tumor specimen BA2930D (aliquot aq-BA2930D) from BEATAML1.0 case 2453, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 76.4 years (27,908 days).
Specimen BA2930D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16698a4c-b0ed-4541-8edb-ef985603ce8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2205D (Solid Tissue Normal), aliquot aq-BA2205D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f48665d-829c-42cc-8bd6-bd7016f0b6f1

The open-access MAF lists 10 somatic variants for this specimen: 10 protein-altering or splice-affecting.
By variant classification: Missense Mutation 8, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2508_2510del p.I836del | In Frame Del (DEL) | VAF 14/132 reads (11%) | catalogued as rs121913490; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- AS3MT | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.677); catalogued as rs1564789532, COSV54915979; called by muse, mutect2, varscan2
- IKBKG | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as CD141303; called by muse, mutect2
- SF3B1 | c.1986C>G p.H662Q | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs778467242, COSV59205547, COSV59208501; called by muse, mutect2, varscan2
- SPTBN5 | c.1962G>C p.W654C | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV100311958; called by mutect2, varscan2
- SUSD5 | c.1538C>T p.T513M | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.732); catalogued as rs372702857; called by muse, mutect2, varscan2
- ANKRD62 | c.2728C>T p.L910F | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLIP3 | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); called by muse, mutect2
- RIMBP3 | c.2615A>T p.D872V | Missense Mutation (SNP) | VAF 33/319 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- RUNX1 | c.931del p.A311Rfs*256 (on ENST00000344691 / NM_001001890.3; = p.A338Rfs*256 on NM_001754.5) | Frame Shift Del (DEL) | VAF 18/28 reads (64%) | called by mutect2, pindel, varscan2
